Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3970, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3970-01A (Primary Tumor).

Diagnosis:

Left hemicolectomy preparation with a moderately differentiated, invasive adenocarcinoma with infiltration of the pericolic fatty tissue. There is a further tubulovillous adenoma with focal, severe dysplasia (synonym: severe intraepithelial neoplasia).

The tumor classification of the adenocarcinoma is: G2, pT3 N0 (0/27) L0 V0 R0.

Source: NCI Genomic Data Commons file b23495ab-8e61-45f1-b7a2-71ee73e3be01 (TCGA-AA-3970.72BFFE46-A121-4488-ACDC-0FFD4E57CABE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).